Somatic mutation profile of tumor specimen TARGET-10-PANZGN-09A (aliquot TARGET-10-PANZGN-09A-01D) from TARGET case TARGET-10-PANZGN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (616 days).
Specimen TARGET-10-PANZGN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d298e2f3-6dd0-4175-bc15-501285946eea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANZGN-14A (Bone Marrow Normal), aliquot TARGET-10-PANZGN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0320618d-a745-42b8-a5d2-e8e9693e3fd6

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCAPG | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV52271396; called by muse, mutect2, varscan2
- ZFHX4 | c.1020del p.K340Nfs*15 | Frame Shift Del (DEL) | VAF 93/258 reads (36%) | catalogued as rs774274741; called by mutect2, pindel, varscan2
- PGAP1 | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NCOR2 | c.3576G>A p.A1192= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs533216923; called by muse, mutect2, varscan2
- NEB | c.13878C>T p.Y4626= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as rs761964375; called by muse, mutect2, varscan2
